Somatic mutation profile of tumor specimen MMRF_2425_1_BM_CD138pos (aliquot MMRF_2425_1_BM_CD138pos_T1_KHS5U_L11235) from MMRF case MMRF_2425, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 55.0 years (20,089 days).
Specimen MMRF_2425_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68cdfa60-35ef-4403-8a96-8c02f3d58277.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2425_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2425_1_PB_Whole_C2_KHS5U_L11236; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb8e569c-b294-486b-ae17-61315b55dcc7

The open-access MAF lists 173 somatic variants for this specimen: 70 protein-altering or splice-affecting, 20 silent, 83 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, 3'UTR 45, Intron 22, Silent 20, 5'UTR 8, Nonsense Mutation 6, 3'Flank 4, 5'Flank 4, Splice Site 3, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTC1 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.794); catalogued as COSV51761249; called by muse, mutect2, varscan2
- ARHGEF10 | c.1465G>A p.V489I (on ENST00000398564; = p.V464I on NM_014629.4) | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs148840693; called by muse, mutect2, varscan2
- ARNT2 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 60/222 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs369899179; called by muse, mutect2, varscan2
- C14orf28 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV57334182; called by muse, mutect2, varscan2
- CEP83 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 63/194 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs1288256034, COSV60406406; called by muse, mutect2, varscan2
- COL6A1 | c.2419G>A p.A807T | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs143925936; called by muse, mutect2, varscan2
- DNAH17 | c.10052C>T p.T3351M | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.611); catalogued as rs535678813; called by muse, mutect2, varscan2
- DPP10 | c.175+1G>A p.X59_splice | Splice Site (SNP) | VAF 122/279 reads (44%) | catalogued as COSV59678412; called by muse, mutect2, varscan2
- EIF4A1 | c.20C>A p.S7Y | Missense Mutation (SNP) | VAF 141/408 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs199974690, COSV53441875; called by muse, mutect2, varscan2
- HSPA14 | c.16G>A p.V6I | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0.095); catalogued as rs1281709143; called by muse, mutect2, varscan2
- IGHV2-70 | c.265A>T p.T89S | Missense Mutation (SNP) | VAF 43/61 reads (70%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs373471089; called by muse, varscan2
- IGKV4-1 | c.328G>T p.A110S | Missense Mutation (SNP) | VAF 33/39 reads (85%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.763); catalogued as rs775181261; called by muse, mutect2, varscan2
- IGLV3-1 | c.118A>G p.T40A | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as rs189772470; called by muse, varscan2
- IGLV3-1 | c.251A>T p.N84I | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as rs373605544; called by muse, varscan2
- MAGI1 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV100440389; called by muse, mutect2, varscan2
- MICALL2 | c.2248C>T p.R750W | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs773308322, COSV99876342; called by muse, mutect2, varscan2
- MISP | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as rs776345030, COSV53119908; called by muse, mutect2, varscan2
- NWD1 | c.3298G>A p.A1100T | Missense Mutation (SNP) | VAF 42/74 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.37); catalogued as rs191339575, COSV100343831; called by muse, mutect2, varscan2
- PCDHB8 | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV50794655, COSV99177469; called by muse, mutect2, varscan2
- PLPPR3 | c.1228G>C p.E410Q (on ENST00000520876 / NM_001270366.2; = p.E438Q on NM_024888.2) | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.85); PolyPhen benign (0.021); catalogued as rs777593991; called by muse, mutect2, varscan2
- PRSS58 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as rs146814209, COSV101616130; called by muse, mutect2, varscan2
- ROBO1 | c.2422G>T p.G808* | Nonsense Mutation (SNP) | VAF 16/99 reads (16%) | catalogued as COSV71398620; called by muse, mutect2, varscan2
- SEMA5B | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768760804, COSV52104715; called by muse, mutect2, varscan2
- STK17A | c.160C>A p.P54T | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.321); catalogued as COSV60046152; called by muse, mutect2, varscan2
- SVIL | c.1704G>T p.R568S | Missense Mutation (SNP) | VAF 86/220 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV63442562; called by muse, mutect2, varscan2
- TBC1D5 | c.1021C>T p.R341* | Nonsense Mutation (SNP) | VAF 59/192 reads (31%) | catalogued as rs776778743, COSV53768737; called by muse, mutect2, varscan2
- TRIM50 | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs145742720; called by muse, mutect2, varscan2
- UBP1 | c.1306C>T p.R436W | Missense Mutation (SNP) | VAF 75/140 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as rs201743372; called by muse, mutect2, varscan2
- ZNF568 | c.1781C>T p.A594V | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs1483218808; called by muse, mutect2, varscan2
- ACTR3B | c.102T>C p.C34= | Splice Region (SNP) | VAF 36/98 reads (37%) | called by muse, mutect2, varscan2
- AHNAK | c.15073A>G p.M5025V | Missense Mutation (SNP) | VAF 84/232 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ANKRD30A | c.3791A>C p.K1264T (on ENST00000611781; = p.K1208T on NM_052997.2) | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- CIC | c.1275_1287del p.S426Pfs*5 | Frame Shift Del (DEL) | VAF 15/57 reads (26%) | called by mutect2, pindel, varscan2
- CSMD3 | c.1499C>A p.S500* (on ENST00000297405 / NM_001363185.1; = p.S396* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 19/50 reads (38%) | called by muse, mutect2, varscan2
- CUBN | c.1947+2T>A p.X649_splice | Splice Site (SNP) | VAF 28/69 reads (41%) | called by muse, mutect2, varscan2
- EIF3M | c.1107G>T p.L369F | Missense Mutation (SNP) | VAF 80/235 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EIF4G1 | c.110A>G p.Q37R | Missense Mutation (SNP) | VAF 57/220 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- EIF4G1 | c.2567A>G p.D856G (on ENST00000346169 / NM_198241.3; = p.D661G on NM_004953.5) | Missense Mutation (SNP) | VAF 53/210 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- ELL3 | c.1066T>G p.Y356D | Missense Mutation (SNP) | VAF 58/175 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABRA6 | c.691A>C p.T231P | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- GPR6 | c.579G>T p.W193C | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GREB1 | c.4261G>T p.D1421Y | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- GRID2IP | c.2194A>C p.S732R | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- GSN | c.1916A>G p.D639G | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- GTF2I | c.232A>C p.K78Q | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- HDAC2 | c.1463C>A p.P488H | Missense Mutation (SNP) | VAF 14/420 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); called by muse, mutect2
- HDGFL1 | c.252C>A p.N84K | Missense Mutation (SNP) | VAF 50/83 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- IRF8 | c.281A>C p.E94A | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRK2 | c.2105T>G p.V702G | Missense Mutation (SNP) | VAF 60/155 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- NFKB2 | c.2023G>C p.A675P | Missense Mutation (SNP) | VAF 51/133 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- PCLO | c.9904C>T p.Q3302* | Nonsense Mutation (SNP) | VAF 59/121 reads (49%) | called by muse, mutect2, varscan2
- PLIN1 | c.1564A>G p.S522G | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- PLIN3 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- POT1 | c.1894G>A p.D632N | Missense Mutation (SNP) | VAF 121/341 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- PPP4R3C | c.855T>G p.D285E | Missense Mutation (SNP) | VAF 36/42 reads (86%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRS | c.2593G>C p.G865R | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RBM15 | c.2901G>C p.K967N | Missense Mutation (SNP) | VAF 11/233 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2
- RFTN1 | c.280A>T p.K94* | Nonsense Mutation (SNP) | VAF 41/132 reads (31%) | called by muse, mutect2, varscan2
- RIPK3 | c.997A>G p.T333A | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC26A7 | c.790G>A p.V264I | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.038); called by muse, mutect2
- SMCO2 | c.376A>G p.M126V | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SVEP1 | c.10600+1G>A p.X3534_splice | Splice Site (SNP) | VAF 89/237 reads (38%) | called by muse, mutect2, varscan2
- TMPRSS7 | c.1280A>G p.E427G (on ENST00000452346; = p.E301G on NM_001042575.2) | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- TNKS2 | c.3414A>T p.E1138D | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TNKS2 | c.3416A>C p.Y1139S | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- UBE2J2 | c.675C>G p.H225Q | Missense Mutation (SNP) | VAF 84/117 reads (72%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- UGT1A1 | c.1096A>T p.T366S | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- WFDC13 | c.160G>T p.D54Y | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ZDHHC17 | c.811G>T p.V271L | Missense Mutation (SNP) | VAF 69/179 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- ZSWIM5 | c.2152G>T p.E718* | Nonsense Mutation (SNP) | VAF 29/50 reads (58%) | called by muse, mutect2, varscan2
- ADAMTS5 | c.105G>A p.P35= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs905662596; called by muse, mutect2, varscan2
- ARHGAP27 | c.2232A>G p.L744= (on ENST00000428638 / NM_001282290.1; = p.L403= on NM_199282.3) | Silent (SNP) | VAF 33/107 reads (31%) | called by muse, mutect2, varscan2
- CALCOCO2 | c.69C>T p.V23= | Silent (SNP) | VAF 17/79 reads (22%) | called by muse, mutect2, varscan2
- CDC27 | c.123G>A p.L41= | Silent (SNP) | VAF 7/32 reads (22%) | called by muse, mutect2, varscan2
- DNAH11 | c.10125C>A p.T3375= | Silent (SNP) | VAF 102/286 reads (36%) | called by muse, mutect2, varscan2
- FBN2 | c.5607T>C p.N1869= | Silent (SNP) | VAF 45/139 reads (32%) | catalogued as rs1338091470; called by muse, mutect2, varscan2
- GDI2 | c.1053T>A p.A351= | Silent (SNP) | VAF 16/58 reads (28%) | called by muse, varscan2
- IGKJ5 | c.40C>A p.*14= | Silent (SNP) | VAF 82/197 reads (42%) | catalogued as rs181580600; called by muse, varscan2
- IGLV3-1 | c.189G>T p.V63= | Silent (SNP) | VAF 41/109 reads (38%) | catalogued as rs61731686; called by muse, varscan2
- KALRN | c.8673C>T p.N2891= (on ENST00000360013 / NM_001024660.4; = p.N1194= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 51/226 reads (23%) | catalogued as rs758592148, COSV52255832; called by muse, mutect2, varscan2
- KLHL14 | c.171C>T p.Y57= | Silent (SNP) | VAF 41/144 reads (28%) | called by muse, mutect2, varscan2
- MATK | c.573C>T p.D191= (on ENST00000310132 / NM_139355.3; = p.D192= on NM_002378.4) | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as rs763245476; called by muse, mutect2
- MMEL1 | c.1377G>A p.A459= | Silent (SNP) | VAF 53/91 reads (58%) | catalogued as rs371381022; called by muse, mutect2, varscan2
- NPC1L1 | c.1974C>T p.S658= | Silent (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2, varscan2
- OPCML | c.609C>T p.S203= | Silent (SNP) | VAF 37/98 reads (38%) | catalogued as rs560079674, COSV100098884, COSV59417502, COSV59451112; called by muse, mutect2
- PROS1 | c.1881C>T p.F627= | Silent (SNP) | VAF 26/129 reads (20%) | called by muse, mutect2, varscan2
- PTDSS2 | c.1197C>T p.Y399= | Silent (SNP) | VAF 51/116 reads (44%) | catalogued as rs138474032; called by muse, mutect2, varscan2
- SLC25A32 | c.828T>A p.G276= | Silent (SNP) | VAF 58/181 reads (32%) | called by muse, mutect2, varscan2
- SOBP | c.1296C>T p.P432= | Silent (SNP) | VAF 159/440 reads (36%) | catalogued as COSV57999802; called by muse, mutect2, varscan2
- UGT2A1 | c.1080T>C p.L360= | Silent (SNP) | VAF 73/227 reads (32%) | called by muse, mutect2, varscan2
- AC092032.2 | chr7:4976317 G>A | 5'Flank (SNP) | VAF 75/229 reads (33%) | called by muse, mutect2, varscan2
- ADGRL3 | c.583+385T>A | Intron (SNP) | VAF 13/25 reads (52%) | called by muse, mutect2, varscan2
- ANK1 | c.*197G>A | 3'UTR (SNP) | VAF 43/101 reads (43%) | catalogued as rs1007422175; called by muse, mutect2, varscan2
- BCL7A | chr12:122021401 del GCTCGCATTTGAACAGG | 5'Flank (DEL) | VAF 47/134 reads (35%) | called by mutect2, pindel, varscan2
- BTAF1 | c.*880G>A | 3'UTR (SNP) | VAF 12/82 reads (15%) | called by muse, mutect2, varscan2
- BTG1 | c.-204G>A | 5'UTR (SNP) | VAF 8/26 reads (31%) | called by muse, varscan2
- C1QTNF1 | chr17:79020115 G>A | 5'Flank (SNP) | VAF 24/68 reads (35%) | called by muse, mutect2, varscan2
- C1orf198 | c.*2579C>T | 3'UTR (SNP) | VAF 14/27 reads (52%) | called by muse, mutect2, varscan2
- CCN4 | c.-8G>A | 5'UTR (SNP) | VAF 21/47 reads (45%) | catalogued as rs775272326, COSV99136907; called by muse, mutect2, varscan2
- CD200R1 | c.*873A>G | 3'UTR (SNP) | VAF 43/135 reads (32%) | called by muse, mutect2, varscan2
- CDC16 | c.*69T>C | 3'UTR (SNP) | VAF 20/23 reads (87%) | called by muse, mutect2, varscan2
- CDH19 | c.*1281T>C | 3'UTR (SNP) | VAF 23/71 reads (32%) | called by muse, mutect2, varscan2
- CSAD | c.*399C>T | 3'UTR (SNP) | VAF 7/19 reads (37%) | catalogued as rs768622237; called by muse, varscan2
- CYP3A5 | c.-64A>T | 5'UTR (SNP) | VAF 25/89 reads (28%) | called by muse, mutect2, varscan2
- DCBLD1 | c.*497T>C | 3'UTR (SNP) | VAF 23/56 reads (41%) | catalogued as rs879650695; called by muse, mutect2, varscan2
- DENND1B | c.*1851G>A | 3'UTR (SNP) | VAF 16/53 reads (30%) | called by muse, mutect2, varscan2
- DGKB | c.*1988G>A | 3'UTR (SNP) | VAF 28/79 reads (35%) | catalogued as rs978170637; called by muse, mutect2, varscan2
- DNAL1 | chr14:73644970 C>T | 5'Flank (SNP) | VAF 29/87 reads (33%) | called by muse, mutect2, varscan2
- DNM2 | c.1893+41C>T | Intron (SNP) | VAF 46/83 reads (55%) | catalogued as rs1451118631; called by muse, mutect2, varscan2
- EDEM1 | c.*777G>A | 3'UTR (SNP) | VAF 12/44 reads (27%) | called by muse, mutect2, varscan2
- EXD3 | c.*10G>C | 3'UTR (SNP) | VAF 42/96 reads (44%) | called by muse, mutect2, varscan2
- FAF1 | c.*1660T>C | 3'UTR (SNP) | VAF 29/48 reads (60%) | called by muse, mutect2, varscan2
- FLRT2 | c.*204A>C | 3'UTR (SNP) | VAF 11/42 reads (26%) | called by muse, mutect2, varscan2
- GFUS | c.147-136A>G | Intron (SNP) | VAF 67/160 reads (42%) | catalogued as rs758035349; called by muse, mutect2, varscan2
- GNB1L | c.*3640C>T | 3'UTR (SNP) | VAF 34/70 reads (49%) | catalogued as rs1327289940; called by muse, mutect2, varscan2
- GPX1 | c.253-116G>T | Intron (SNP) | VAF 115/508 reads (23%) | called by muse, mutect2, varscan2
- GRK7 | c.-119C>T | 5'UTR (SNP) | VAF 61/221 reads (28%) | catalogued as rs1203919408; called by muse, mutect2, varscan2
- H2BC21 | c.*266C>T | 3'UTR (SNP) | VAF 19/50 reads (38%) | called by muse, mutect2, varscan2
- HNMT | c.*1853A>C | 3'UTR (SNP) | VAF 41/81 reads (51%) | called by muse, mutect2, varscan2
- HS3ST1 | c.*1168A>C | 3'UTR (SNP) | VAF 29/74 reads (39%) | called by muse, mutect2, varscan2
- HSDL2 | c.*1526A>C | 3'UTR (SNP) | VAF 26/68 reads (38%) | called by muse, mutect2, varscan2
- HSDL2 | c.*1527G>C | 3'UTR (SNP) | VAF 27/70 reads (39%) | called by muse, mutect2, varscan2
- IL1RL1 | c.970+756G>C | Intron (SNP) | VAF 22/47 reads (47%) | called by muse, mutect2, varscan2
- IL20RA | c.*971G>A | 3'UTR (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2, varscan2
- IL2RA | c.*865C>T | 3'UTR (SNP) | VAF 33/84 reads (39%) | called by muse, mutect2, varscan2
- IMPDH2 | c.1151-35T>G | Intron (SNP) | VAF 66/212 reads (31%) | catalogued as rs528413131; called by muse, mutect2, varscan2
- IQUB | c.868-68A>T | Intron (SNP) | VAF 8/15 reads (53%) | called by muse, mutect2, varscan2
- IRS2 | c.*403A>T | 3'UTR (SNP) | VAF 29/47 reads (62%) | called by muse, mutect2, varscan2
- KRTAP21-1 | c.*25G>T | 3'UTR (SNP) | VAF 77/184 reads (42%) | called by muse, mutect2, varscan2
- LMO3 | c.206+39C>A | Intron (SNP) | VAF 11/33 reads (33%) | catalogued as rs771875185; called by muse, mutect2, varscan2
- MEF2C | chr5:88718936 A>G | 3'Flank (SNP) | VAF 21/74 reads (28%) | called by muse, mutect2, varscan2
- MRPL18 | c.52+132A>C | Intron (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
- MXD4 | c.*621A>T | 3'UTR (SNP) | VAF 44/128 reads (34%) | called by muse, mutect2, varscan2
- MYO7A | c.*50G>C | 3'UTR (SNP) | VAF 25/59 reads (42%) | called by muse, mutect2, varscan2
- NIN | c.981+28A>T | Intron (SNP) | VAF 80/196 reads (41%) | catalogued as rs1337551925; called by muse, mutect2, varscan2
- NLGN1 | c.*1047A>G | 3'UTR (SNP) | VAF 14/72 reads (19%) | called by muse, mutect2, varscan2
- NSG2 | c.*738A>G | 3'UTR (SNP) | VAF 22/50 reads (44%) | called by muse, mutect2, varscan2
- PABPC5 | c.*1676T>C | 3'UTR (SNP) | VAF 21/31 reads (68%) | called by muse, mutect2, varscan2
- PCDH11X | c.3033+3674T>G | Intron (SNP) | VAF 146/188 reads (78%) | catalogued as COSV100014428; called by muse, mutect2, varscan2
- PCDHA10 | c.2388+2941G>A | Intron (SNP) | VAF 34/114 reads (30%) | catalogued as COSV56482301; called by muse, mutect2, varscan2
- PIAS2 | c.1508+52C>G | Intron (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- PLEKHB1 | c.248-335C>A | Intron (SNP) | VAF 18/46 reads (39%) | catalogued as rs554220669; called by muse, mutect2, varscan2
- PSD3 | c.*4114C>T | 3'UTR (SNP) | VAF 17/33 reads (52%) | called by muse, mutect2, varscan2
- PSMA1 | c.414+51G>T | Intron (SNP) | VAF 11/29 reads (38%) | called by muse, mutect2, varscan2
- PTK6 | c.*387G>C | 3'UTR (SNP) | VAF 94/250 reads (38%) | catalogued as rs911450049; called by muse, mutect2, varscan2
- PWWP3B | c.*394dup | 3'UTR (INS) | VAF 31/55 reads (56%) | called by mutect2, pindel, varscan2
- RAB21 | c.*992G>T | 3'UTR (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2, varscan2
- RAB21 | c.*993A>C | 3'UTR (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2, varscan2
- RABGAP1L | c.139-26A>G | Intron (SNP) | VAF 44/116 reads (38%) | called by muse, varscan2
- RASGRF1 | c.3542+1774A>C | Intron (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2, varscan2
- REG3A | c.76+76G>A | Intron (SNP) | VAF 23/79 reads (29%) | catalogued as rs970837356; called by muse, mutect2
- RNF125 | c.*224del | 3'UTR (DEL) | VAF 32/86 reads (37%) | called by mutect2, varscan2
- SCGB3A1 | c.*42C>A | 3'UTR (SNP) | VAF 14/166 reads (8%) | called by muse, mutect2
- SDC2 | c.*403C>T | 3'UTR (SNP) | VAF 43/103 reads (42%) | called by muse, mutect2, varscan2
- SEC22C | c.*230G>A | 3'UTR (SNP) | VAF 35/143 reads (24%) | catalogued as rs534912432; called by muse, mutect2, varscan2
- SLC11A2 | chr12:50981487 G>A | 3'Flank (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- SNAPIN | c.*423G>T | 3'UTR (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
- SNORD50B | chr6:85677514 A>C | 3'Flank (SNP) | VAF 18/48 reads (38%) | catalogued as rs954577709; called by muse, varscan2
- TBC1D20 | c.*2204A>T | 3'UTR (SNP) | VAF 21/53 reads (40%) | called by muse, mutect2, varscan2
- TCAIM | c.165+1173G>A | Intron (SNP) | VAF 15/53 reads (28%) | called by muse, mutect2, varscan2
- TNRC6B | c.*1374G>A | 3'UTR (SNP) | VAF 17/65 reads (26%) | called by muse, mutect2, varscan2
- TNS4 | c.*1430G>T | 3'UTR (SNP) | VAF 13/48 reads (27%) | called by muse, mutect2, varscan2
- TRAF3IP1 | c.*819G>A | 3'UTR (SNP) | VAF 34/82 reads (41%) | called by muse, mutect2
- TRAPPC10 | c.790+402C>T | Intron (SNP) | VAF 124/328 reads (38%) | called by muse, mutect2, varscan2
- TRIM37 | c.-8C>T | 5'UTR (SNP) | VAF 75/147 reads (51%) | catalogued as rs917958276; called by muse, mutect2, varscan2
- VIL1 | c.1102+99T>G | Intron (SNP) | VAF 96/266 reads (36%) | called by muse, mutect2, varscan2
- VSIG8 | c.972-292C>T | Intron (SNP) | VAF 69/174 reads (40%) | catalogued as COSV63653767; called by muse, mutect2, varscan2
- WARS1 | c.-47T>C | 5'UTR (SNP) | VAF 47/162 reads (29%) | called by muse, mutect2, varscan2
- ZBTB26 | chr9:122915857 A>G | 3'Flank (SNP) | VAF 28/70 reads (40%) | called by muse, mutect2, varscan2
- ZNF254 | c.-2A>G | 5'UTR (SNP) | VAF 88/229 reads (38%) | called by muse, mutect2, varscan2
- ZNF300 | c.*475dup | 3'UTR (INS) | VAF 14/38 reads (37%) | catalogued as rs957999205; called by mutect2, pindel, varscan2
- ZNF322 | c.-37G>C | 5'UTR (SNP) | VAF 45/138 reads (33%) | called by muse, mutect2, varscan2
- ZNF664 | c.*2291G>T | 3'UTR (SNP) | VAF 20/61 reads (33%) | called by muse, mutect2, varscan2
